Somatic mutation profile of tumor specimen 0DTREJ from CCDI case PBCKEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,903 days).
Specimen 0DTREJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db9d14dc-cbb6-43b6-97d5-14435c73b04d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTREQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/212ae711-f1b5-426a-9ed3-8898ae33a7c8

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLVAP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99391481; called by muse, mutect2
- PSME4 | c.2948G>A p.R983K | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101122797; called by muse, mutect2, varscan2
- SEC31A | c.1783A>G p.M595V (on ENST00000355196 / NM_001318120.1; = p.M556V on NM_016211.4) | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV52344596; called by muse, mutect2
- C17orf75 | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 166/597 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBFA2T2 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTDNEP1 | c.403del p.E135Rfs*49 | Frame Shift Del (DEL) | VAF 104/158 reads (66%) | called by mutect2, pindel, varscan2
- DTX3L | c.2154-2A>T p.X718_splice | Splice Site (SNP) | VAF 116/245 reads (47%) | called by muse, mutect2, varscan2
- EVI5L | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- GPR142 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- LATS1 | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- MAP2K4 | c.657A>T p.L219F | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP6 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 165/361 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMEM101 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 37/508 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- XPO1 | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRM4 | c.678G>A p.S226= | Silent (SNP) | VAF 34/336 reads (10%) | catalogued as rs893104954, COSV65211669; called by muse, mutect2, varscan2
- HSD11B1 | c.138C>T p.I46= | Silent (SNP) | VAF 232/505 reads (46%) | catalogued as rs149277936; called by muse, mutect2, varscan2
- SPIC | c.528C>T p.Y176= | Silent (SNP) | VAF 43/360 reads (12%) | catalogued as rs759289491, COSV54690341; called by muse, mutect2, varscan2
